Gene-level copy-number profile of tumor specimen TCGA-BC-A10Y-01A from TCGA case TCGA-BC-A10Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3; Age at diagnosis: 76.8 years (28,049 days).
Specimen TCGA-BC-A10Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d8ac86c0-6dcc-4ee3-87e5-e57963beeb7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A10Y-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf03617a-0c54-4895-94b5-2ce2851f367b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 8,640; copy number 2: 44,685; copy number 3: 6,057; copy number 4: 419; copy number 5: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A10Y-01A-11D-A12Y-01): tumor purity 0.92, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–87,971,930, 4 genes (within-gene range 0–1): KLLN, PTEN, AC063965.2, RPL11P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,651,706–178,652,282, 1 gene, copy number 5: AL137796.1.
- chr4:178,406,695–178,406,830, 1 gene, copy number 5: RNA5SP173.
- chr4:179,856,853–180,059,792, 2 genes, copy number 5 (within-gene range 3–5): AC021193.1, AC108169.1.
- chr4:184,826,607–184,911,352, 5 genes, copy number 5 (within-gene range 3–5): AC084871.3, MIR3945HG, MIR3945, LINC01093, AC084871.2.
- chr14:73,787,355–73,840,609, 3 genes, copy number 5: AC005520.2, LINC02274, AC005520.4.
- chr14:73,858,061–73,858,165, 1 gene, copy number 5: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 6,262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
